Somatic mutation profile of tumor specimen MP2PRT-PAVFXT-TMP1-A (aliquot MP2PRT-PAVFXT-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVFXT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,717 days).
Specimen MP2PRT-PAVFXT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a86df61-e207-4bd3-91af-c20e19f3967b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVFXT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVFXT-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8170bbd-b108-471d-807d-bd84ba91443e

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Splice Site 1, In Frame Ins 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD30A | c.1325T>C p.L442S (on ENST00000611781; = p.L386S on NM_052997.2) | Missense Mutation (SNP) | VAF 100/212 reads (47%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.969); catalogued as COSV64621099; called by muse, mutect2, varscan2
- ARMC3 | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 114/294 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201164034; called by muse, mutect2, varscan2
- BAP1 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 164/371 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as rs770422186, COSV56240811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTLN | c.1481G>T p.R494L | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV52073851; called by muse, mutect2, varscan2
- EPS8 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 101/259 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM83B | c.2805T>A p.S935R | Missense Mutation (SNP) | VAF 139/329 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGFN1 | c.1079C>A p.P360H | Missense Mutation (SNP) | VAF 167/408 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- IGHV4-59 | c.347_348insCGGTCCCGAGG p.R116Sfs*? | Frame Shift Ins (INS) | VAF 9/47 reads (19%) | called by mutect2, pindel
- IGKV1OR2-108 | chr2:113406868 CCATTCACA>GGG | Missense Mutation (DEL) | VAF 56/72 reads (78%) | called by pindel, varscan2*
- IPO5 | c.3248_3249insGCCCCCGCCCCC p.S1083delinsRPPPP | In Frame Ins (INS) | VAF 67/216 reads (31%) | called by mutect2, pindel*, varscan2
- LRRC66 | c.1030G>C p.G344R | Missense Mutation (SNP) | VAF 235/445 reads (53%) | SIFT tolerated (0.24); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- MUC4 | c.2272G>C p.A758P | Missense Mutation (SNP) | VAF 22/681 reads (3%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.675); called by muse, mutect2
- TRAV26-2 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 148/298 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- UGGT2 | c.1977+1G>C p.X659_splice | Splice Site (SNP) | VAF 35/80 reads (44%) | called by muse, mutect2, varscan2
- CHST8 | c.1176C>T p.F392= | Silent (SNP) | VAF 199/476 reads (42%) | called by muse, mutect2, varscan2
- COL9A1 | c.2622C>T p.D874= | Silent (SNP) | VAF 187/417 reads (45%) | catalogued as rs149139869; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC16 | c.22138C>A p.R7380= | Silent (SNP) | VAF 139/318 reads (44%) | catalogued as COSV101201912, COSV67481398; called by muse, mutect2, varscan2
